Surgical pathology report (de-identified scan), TCGA case TCGA-EA-A5ZE, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Asterand, specimen TCGA-EA-A5ZE-01A (Primary Tumor).

Gross Description: Tumor is located in cervix and occupying cervical majority. It is 4x3x2cm in size, firm and white-gray surface.

Microscopic Description: Squamous cell are hyperplastic to infiltrate in stroma or fat tissue. Tumor tissue arranges in the form of group or sheets or trabecular of tumor cells. The malignant cells have moderate, light eosinophilic cytoplasm. The nuclei are enlarged, variability in size and shape, containing coarse clumped chromatin with prominent nucleoli. Mitotic figures are present. Stroma is invasion of lymphocytes.

Diagnosis Details: Squamous cell carcinoma, Grade III, infiltrating fat tissue

Comments:

Formatted Path Reports: CERVIX TISSUE CHECKLIST

Specimen type: Hysterectomy

Tumor site: Cervix

Tumor size: 4 x 3 x 2 cm

Histologic type: Squamous cell carcinoma

Histologic grade: Poorly differentiated

Tumor extent: Lesion less than 4.0 cm

Lymph nodes: Not specified

Lymphatic invasion: Present

Venous invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

ICD-O-3

Carcinoma, squamous cell NOS
8070/3

Site: Cervix NOS C53.9

720 4/2/13

Source: NCI Genomic Data Commons file 0a6ed450-2d82-4eb3-8905-84c48ce0c3ca (TCGA-EA-A5ZE.316CE4CE-B951-4DFA-B2CC-B0512AA86871.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).